Somatic mutation profile of tumor specimen 0DRB5R from CCDI case PBCFRR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Neuroepithelioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.1 years (4,420 days).
Specimen 0DRB5R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9cc084e-ba1e-46ef-9666-ba7917573255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DRB5U (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5f854b3-2da3-4475-97a8-4f0b65c7368a

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDC5L | c.1276C>T p.R426W | Missense Mutation (SNP) | VAF 155/779 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV101014918; called by muse, mutect2, varscan2
- PUS7 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 357/1164 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIG4 | c.663G>A p.L221= | Silent (SNP) | VAF 69/1332 reads (5%) | called by muse, mutect2
- PTER | c.438C>T p.T146= | Silent (SNP) | VAF 31/736 reads (4%) | catalogued as rs991604409, COSV54345661; called by muse, mutect2
- TEX13D | c.1158G>A p.L386= | Silent (SNP) | VAF 18/592 reads (3%) | called by muse, mutect2
- TMPRSS7 | c.513C>T p.G171= (on ENST00000452346; = p.G58= on NM_001042575.2) | Silent (SNP) | VAF 268/1124 reads (24%) | catalogued as rs757337665, COSV69983379; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 30/291 reads (10%) | called by muse, varscan2
